Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3BN, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3BN-01A (Primary Tumor).

lw 10/15/11

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1) THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy.

TUMOR SITE:

Right lobe

100-0-3

carcinoma, papillary, thyroid, 8260/3

HISTOLOGIC TYPE:

Papillary carcinoma.

Site: thyroid, No's C73.9

lw
10/15/11

TUMOR SIZE:

Greatest dimension: 3 cm.

FOCALITY:

Unifocal

LYMPH NODES:

None submitted.

EXTENT OF INVASION

PRIMARY TUMOR:

pT2: Tumor > 2 cm but <4 cm, limited to thyroid.

REGIONAL LYMPH NODES:

pNx: Cannot be assessed.

DISTANT METASTASIS:

pMx: Cannot be assessed.

MARGINS:

Margins are uninvolved.

VENOUS/LYMPHATIC INVASION:

Absent.

ADDITIONAL PATHOLOGIC FINDINGS:

Thyroiditis (mild)

Source: NCI Genomic Data Commons file 86947105-3a79-4695-895b-1a5ec1b73564 (TCGA-ET-A3BN.285F05E8-2C8E-4D4A-968C-AE1F3D5882FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).